Somatic mutation profile of tumor specimen MP2PRT-PAUFMP-TMP1-A (aliquot MP2PRT-PAUFMP-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFMP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,056 days).
Specimen MP2PRT-PAUFMP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0412f88f-677b-4947-b7ec-e7f932fc3127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFMP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFMP-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b658abe-3d13-4be8-aa73-4e53f092dd6d

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MECP2 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 37/603 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs587783134; ClinVar: uncertain significance; called by muse, mutect2
- VPS13D | c.4169G>A p.R1390Q | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as rs555254469; called by muse, mutect2
- IGHV1-3 | c.337_353delinsCCCGGAC p.Y113Pfs*? | Frame Shift Del (DEL) | VAF 27/44 reads (61%) | called by pindel, varscan2*
- UGT2A1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A2 | c.1689C>T p.G563= | Silent (SNP) | VAF 39/325 reads (12%) | catalogued as rs761007313; called by muse, mutect2, varscan2
- GRIK1 | c.924C>T p.P308= | Silent (SNP) | VAF 89/291 reads (31%) | catalogued as rs148983818; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKAG3 | c.666C>T p.N222= | Silent (SNP) | VAF 125/352 reads (36%) | catalogued as rs200735141, COSV52101464; called by muse, mutect2, varscan2
- RERG | c.570T>C p.I190= | Silent (SNP) | VAF 68/261 reads (26%) | called by muse, mutect2
